Somatic mutation profile of tumor specimen MMRF_2807_1_BM_CD138pos (aliquot MMRF_2807_1_BM_CD138pos_T1_KHS5U_L15741) from MMRF case MMRF_2807, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow.
Specimen MMRF_2807_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 001fcf50-8bec-4026-b0f6-bd6b9530fb40.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2807_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2807_1_PB_WBC_C3_KHS5U_L15785; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/feac96aa-b0fe-4225-a19b-2f59e18d71be

The open-access MAF lists 70 somatic variants for this specimen: 21 protein-altering or splice-affecting, 7 silent, 42 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 22, Missense Mutation 19, Intron 11, Silent 7, 3'Flank 3, 5'UTR 3, RNA 2, Splice Site 1, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA8 | c.1967C>T p.A656V | Missense Mutation (SNP) | VAF 68/175 reads (39%) | SIFT tolerated (0.47); PolyPhen benign (0.021); catalogued as rs145869753; called by muse, mutect2, varscan2
- MXRA5 | c.3637C>T p.P1213S | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs200937337; called by muse, mutect2, varscan2
- SCN5A | c.2321A>G p.Y774C | Missense Mutation (SNP) | VAF 62/113 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs1450628433; called by muse, varscan2
- ACCSL | c.130T>G p.F44V | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.024); called by muse, mutect2
- BAG6 | c.156C>G p.I52M | Missense Mutation (SNP) | VAF 73/234 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC88C | c.4382C>T p.P1461L | Missense Mutation (SNP) | VAF 59/109 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CTSV | c.692G>T p.G231V | Missense Mutation (SNP) | VAF 57/112 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- CYLC1 | c.863C>T p.T288I | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- DMD | c.3355_3368del p.A1119Cfs*5 | Frame Shift Del (DEL) | VAF 47/149 reads (32%) | called by mutect2, varscan2
- FLRT3 | c.1402G>T p.A468S | Missense Mutation (SNP) | VAF 61/143 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- KCNMA1 | c.1703T>C p.L568P | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- KDM6B | c.1703C>T p.P568L | Missense Mutation (SNP) | VAF 55/133 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- LARP4B | c.574A>T p.T192S | Missense Mutation (SNP) | VAF 54/140 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.137); called by muse, varscan2
- MROH2B | c.2442-2A>T p.X814_splice | Splice Site (SNP) | VAF 25/50 reads (50%) | called by muse, mutect2, varscan2
- NCBP3 | c.544C>G p.P182A | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.607); called by muse, varscan2
- NEK11 | c.1775A>T p.K592M | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- OR1L1 | c.739A>G p.I247V (on ENST00000373686; = p.I197V on NM_001005236.3) | Missense Mutation (SNP) | VAF 126/288 reads (44%) | SIFT tolerated (0.62); PolyPhen benign (0.023); called by muse, varscan2
- SYT7 | c.1163T>C p.I388T | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- TRPC5 | c.2872A>C p.M958L | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- TSC2 | c.259G>T p.D87Y | Missense Mutation (SNP) | VAF 23/27 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VPS41 | c.99A>T p.E33D | Missense Mutation (SNP) | VAF 217/416 reads (52%) | SIFT tolerated (0.39); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- DNAJC1 | c.268C>T p.L90= | Silent (SNP) | VAF 33/71 reads (46%) | called by muse, mutect2, varscan2
- EGLN1 | c.804C>A p.T268= | Silent (SNP) | VAF 17/359 reads (5%) | called by muse, mutect2
- IL1RL1 | c.288G>A p.R96= | Silent (SNP) | VAF 28/53 reads (53%) | catalogued as COSV52117083; called by muse, varscan2
- NPTXR | c.342C>T p.G114= | Silent (SNP) | VAF 13/28 reads (46%) | called by muse, mutect2, varscan2
- PGBD5 | c.801G>A p.K267= (on ENST00000525115; = p.K336= on NM_001258311.2) | Silent (SNP) | VAF 64/232 reads (28%) | called by muse, mutect2, varscan2
- SAMD10 | c.561G>A p.G187= | Silent (SNP) | VAF 50/118 reads (42%) | called by muse, mutect2, varscan2
- ZNF560 | c.2184T>A p.T728= | Silent (SNP) | VAF 35/78 reads (45%) | called by muse, mutect2, varscan2
- AACS | c.*314A>C | 3'UTR (SNP) | VAF 66/147 reads (45%) | called by muse, mutect2, varscan2
- AC025538.1 | n.452C>G | RNA (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2
- AJUBA | c.1007-296A>G | Intron (SNP) | VAF 22/52 reads (42%) | catalogued as rs932985986; called by muse, mutect2, varscan2
- AK4 | c.*465C>A | 3'UTR (SNP) | VAF 13/26 reads (50%) | called by muse, mutect2, varscan2
- ANOS1 | c.*3337G>A | 3'UTR (SNP) | VAF 42/109 reads (39%) | called by muse, mutect2, varscan2
- ARHGEF6 | c.*1669del | 3'UTR (DEL) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- ASH1L | c.*1025C>G | 3'UTR (SNP) | VAF 22/54 reads (41%) | called by muse, mutect2, varscan2
- BSDC1 | c.11+103G>A | Intron (SNP) | VAF 102/194 reads (53%) | called by muse, mutect2, varscan2
- CD300E | c.*203C>A | 3'UTR (SNP) | VAF 10/69 reads (14%) | called by muse, mutect2, varscan2
- CERS6 | c.*2446G>A | 3'UTR (SNP) | VAF 4/92 reads (4%) | catalogued as rs1210655745; called by muse, mutect2
- CES3 | c.287+31G>C | Intron (SNP) | VAF 45/103 reads (44%) | catalogued as rs1173199925; called by muse, mutect2, varscan2
- CHRNA7 | c.56-42C>A | Intron (SNP) | VAF 35/81 reads (43%) | called by muse, mutect2, varscan2
- DHFR | c.137-508T>G | Intron (SNP) | VAF 14/37 reads (38%) | called by muse, mutect2, varscan2
- DLG2 | c.-180C>T | 5'UTR (SNP) | VAF 26/106 reads (25%) | called by muse, varscan2
- FRMD4A | c.46-149385del | Intron (DEL) | VAF 31/75 reads (41%) | called by mutect2, pindel, varscan2
- GABRB2 | c.*2982A>G | 3'UTR (SNP) | VAF 36/56 reads (64%) | catalogued as rs1051472373; called by muse, mutect2, varscan2
- GPR158 | c.*1235A>G | 3'UTR (SNP) | VAF 32/74 reads (43%) | called by muse, mutect2, varscan2
- HHIPL1 | c.*2232G>A | 3'UTR (SNP) | VAF 46/96 reads (48%) | called by muse, mutect2, varscan2
- HRH4 | c.*727G>C | 3'UTR (SNP) | VAF 17/41 reads (41%) | called by muse, varscan2
- IFIT3 | c.*742T>G | 3'UTR (SNP) | VAF 19/38 reads (50%) | called by muse, mutect2, varscan2
- INPP4B | chr4:142026872 G>A | 3'Flank (SNP) | VAF 15/45 reads (33%) | called by muse, mutect2, varscan2
- IRAG1 | c.*1826A>C | 3'UTR (SNP) | VAF 32/97 reads (33%) | called by muse, mutect2, varscan2
- LY6K | c.217+265T>C | Intron (SNP) | VAF 6/17 reads (35%) | called by muse, mutect2, varscan2
- MRAS | c.*1047C>A | 3'UTR (SNP) | VAF 29/84 reads (35%) | called by muse, mutect2, varscan2
- NPY2R | c.*1564del | 3'UTR (DEL) | VAF 16/40 reads (40%) | called by mutect2, varscan2
- NRXN3 | c.-325G>A | 5'UTR (SNP) | VAF 49/132 reads (37%) | called by muse, mutect2, varscan2
- NTRK2 | c.1397-56177C>T | Intron (SNP) | VAF 18/54 reads (33%) | called by muse, varscan2
- PEG10 | c.*1224T>A | 3'UTR (SNP) | VAF 39/85 reads (46%) | called by muse, mutect2, varscan2
- PIP5K1C | c.*115A>T | 3'UTR (SNP) | VAF 14/23 reads (61%) | called by muse, mutect2, varscan2
- POMT2 | c.*2359A>T | 3'UTR (SNP) | VAF 12/68 reads (18%) | catalogued as rs564345093, COSV53611385; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRSS30P | n.2820T>G | RNA (SNP) | VAF 42/57 reads (74%) | called by muse, mutect2, varscan2
- PTPN12 | c.-32del | 5'UTR (DEL) | VAF 4/45 reads (9%) | catalogued as rs758991895; called by pindel, varscan2
- RASGEF1C | c.301-65C>T | Intron (SNP) | VAF 12/32 reads (38%) | catalogued as rs1393069520; called by muse, mutect2
- RAX | c.*85C>A | 3'UTR (SNP) | VAF 23/41 reads (56%) | called by muse, mutect2, varscan2
- RAX | c.*84C>A | 3'UTR (SNP) | VAF 23/41 reads (56%) | called by muse, mutect2, varscan2
- SCD5 | c.*1069T>A | 3'UTR (SNP) | VAF 10/84 reads (12%) | called by muse, mutect2, varscan2
- SYCE1 | chr10:133567870 T>C | 5'Flank (SNP) | VAF 13/23 reads (57%) | called by muse, mutect2
- TCF15 | c.*381A>G | 3'UTR (SNP) | VAF 61/150 reads (41%) | called by muse, mutect2, varscan2
- TMA16 | c.389-120C>A | Intron (SNP) | VAF 16/29 reads (55%) | called by muse, varscan2
- TTC39A | c.1253+133C>A | Intron (SNP) | VAF 18/43 reads (42%) | catalogued as COSV52957857; called by mutect2, varscan2
- VASH2 | chr1:212990152 A>G | 3'Flank (SNP) | VAF 7/92 reads (8%) | called by muse, mutect2
- VEGFA | chr6:43786390 G>A | 3'Flank (SNP) | VAF 12/40 reads (30%) | called by mutect2, varscan2
